Somatic mutation profile of tumor specimen MMRF_1573_1_BM_CD138pos (aliquot MMRF_1573_1_BM_CD138pos_T1_KBS5U_L03474) from MMRF case MMRF_1573, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.0 years (27,758 days).
Specimen MMRF_1573_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82891638-0994-4bc4-9403-2bf41c15cc9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1573_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1573_1_PB_Whole_C2_KBS5U_L03486; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6fba7a20-91b6-46b0-aacf-1db7daa367a6

The open-access MAF lists 98 somatic variants for this specimen: 36 protein-altering or splice-affecting, 12 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 25, Silent 12, Intron 10, 5'UTR 7, 5'Flank 5, RNA 3, Frame Shift Ins 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 27/181 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- BMP1 | c.2437G>A p.A813T | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs780689541, COSV60531276; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C12orf60 | c.589A>T p.T197S | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.022); catalogued as COSV57450929; called by muse, mutect2, varscan2
- EXOC7 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1240988133; called by muse, mutect2, varscan2
- GLT6D1 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs752150072, COSV65626935; called by muse, mutect2, varscan2
- GRIN2A | c.1864C>G p.P622A | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58027778; called by muse, mutect2, varscan2
- HNRNPH2 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 94/150 reads (63%) | catalogued as COSV54508573; called by muse, mutect2, varscan2
- HSPA12B | c.1945G>A p.G649S | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1316130972; called by muse, mutect2, varscan2
- IGKV4-1 | c.151T>G p.Y51D | Missense Mutation (SNP) | VAF 40/43 reads (93%) | SIFT tolerated (0.17); PolyPhen benign (0.184); catalogued as rs141709704; called by muse, mutect2, varscan2
- KRAS | c.190T>A p.Y64N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55534434, COSV55579983, COSV55703886; called by muse, mutect2, varscan2
- LTB | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 212/326 reads (65%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs537728367, COSV53000366; called by muse, mutect2, varscan2
- MROH2B | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101270873; called by muse, mutect2, varscan2
- OLAH | c.622G>T p.V208F (on ENST00000378228 / NM_001039702.3; = p.V261F on NM_018324.3) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.173); catalogued as rs754141411; called by muse, mutect2, varscan2
- OR52K1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs371666945, COSV56904565; called by muse, mutect2, varscan2
- PCLO | c.9963C>A p.D3321E | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV100427234, COSV61612988; called by muse, mutect2, varscan2
- ROBO3 | c.3460G>A p.A1154T | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV100127385; called by muse, mutect2, varscan2
- RP1L1 | c.3487G>A p.V1163I | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs752132792, COSV66753299; called by muse, mutect2, varscan2
- TBL1X | c.1583G>A p.C528Y | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as rs1473664077; called by muse, mutect2, varscan2
- TRBC2 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781847184; called by muse, mutect2, varscan2
- TRMT1L | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.469); catalogued as rs766704960; called by muse, mutect2, varscan2
- TUBB4A | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.332); catalogued as rs1201985530, COSV51164798; called by muse, mutect2, varscan2
- ZSCAN18 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as rs1259002136; called by muse, mutect2, varscan2
- ABCC4 | c.3366+1G>T p.X1122_splice | Splice Site (SNP) | VAF 22/32 reads (69%) | called by muse, mutect2
- COL2A1 | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL6A3 | c.6004T>C p.Y2002H | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DBNDD2 | c.40G>C p.V14L | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- EIF2AK3 | c.730A>C p.T244P | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GRM6 | c.1168G>A p.G390S | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.053); called by muse, mutect2
- MAGI2 | c.1006dup p.A336Gfs*5 | Frame Shift Ins (INS) | VAF 20/190 reads (11%) | called by mutect2, pindel, varscan2
- PPP1R12C | c.1100G>C p.G367A | Missense Mutation (SNP) | VAF 146/233 reads (63%) | SIFT tolerated (0.63); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- PRTFDC1 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RFX2 | c.95_98dup p.L33Ffs*145 | Frame Shift Ins (INS) | VAF 26/71 reads (37%) | called by mutect2, pindel, varscan2
- SCML4 | c.1028C>G p.P343R | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHROOM2 | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UACA | c.3725G>A p.S1242N | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDFY3 | c.9023T>C p.L3008S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ADAM17 | c.1476C>T p.G492= | Silent (SNP) | VAF 52/137 reads (38%) | called by muse, mutect2, varscan2
- BCL11B | c.1743C>T p.G581= (on ENST00000357195 / NM_001282237.2; = p.G510= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as rs1334065341, COSV61734688; called by muse, mutect2
- HERC1 | c.1443T>C p.S481= | Silent (SNP) | VAF 87/344 reads (25%) | catalogued as rs757219350; called by muse, mutect2, varscan2
- MPP3 | c.294G>A p.P98= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs1312010521, COSV68199318; called by muse, mutect2, varscan2
- NLRP6 | c.1537C>T p.L513= | Silent (SNP) | VAF 64/130 reads (49%) | called by muse, mutect2, varscan2
- PNMA2 | c.933G>C p.R311= | Silent (SNP) | VAF 47/111 reads (42%) | called by muse, mutect2, varscan2
- PTGFRN | c.2118G>C p.L706= | Silent (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- PTPRQ | c.3369C>T p.N1123= (on ENST00000616559; = p.N1081= on NM_001145026.2) | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs1207508248, COSV57037190; called by muse, mutect2, varscan2
- PUS3 | c.1242C>T p.L414= | Silent (SNP) | VAF 20/147 reads (14%) | called by muse, mutect2, varscan2
- SUN1 | c.1797C>T p.V599= (on ENST00000405266 / NM_001367651.1; = p.V479= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 10/79 reads (13%) | called by muse, mutect2, varscan2
- TMCC2 | c.1425C>T p.S475= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs147757125; called by mutect2, varscan2
- TTLL3 | c.1275G>A p.V425= | Silent (SNP) | VAF 66/215 reads (31%) | called by muse, mutect2, varscan2
- AC007663.1 | n.840G>A | RNA (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- ADRB1 | c.*584A>G | 3'UTR (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- ANKRD13B | c.*371C>G | 3'UTR (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- BAGE2 | chr21:10452506 A>G | 5'Flank (SNP) | VAF 6/50 reads (12%) | catalogued as rs75112368; called by muse, mutect2, varscan2
- BCL7A | chr12:122021456 C>G | 5'Flank (SNP) | VAF 24/50 reads (48%) | catalogued as rs146519238; called by muse, mutect2, varscan2
- CDC27 | c.*3131A>G | 3'UTR (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- CDH12 | c.*576T>G | 3'UTR (SNP) | VAF 17/43 reads (40%) | called by muse, mutect2, varscan2
- CDK19 | c.*1756G>T | 3'UTR (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- EFCAB14 | c.*255T>A | 3'UTR (SNP) | VAF 37/90 reads (41%) | catalogued as rs942029938; called by muse, mutect2, varscan2
- EPDR1 | c.*1084A>G | 3'UTR (SNP) | VAF 55/85 reads (65%) | called by muse, mutect2, varscan2
- FGD1 | c.-360C>G | 5'UTR (SNP) | VAF 18/97 reads (19%) | called by muse, mutect2, varscan2
- FO681492.1 | c.*774T>C | 3'UTR (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2
- GABRA4 | c.*2603C>G | 3'UTR (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- HNRNPA3P1 | n.14C>T | RNA (SNP) | VAF 21/45 reads (47%) | catalogued as rs768171271; called by muse, mutect2, varscan2
- IMPACT | c.*303C>T | 3'UTR (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- KCNB1 | c.*2527A>T | 3'UTR (SNP) | VAF 7/59 reads (12%) | called by muse, varscan2
- MCM4 | c.-12A>T | 5'UTR (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- MEF2D | c.-57G>A | 5'UTR (SNP) | VAF 30/56 reads (54%) | catalogued as rs910178119; called by muse, mutect2, varscan2
- MMP26 | chr11:4988136 G>A | 5'Flank (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- MMS22L | c.*3509C>T | 3'UTR (SNP) | VAF 3/49 reads (6%) | catalogued as rs1354837078; called by muse, mutect2
- MRGBP | c.*139C>G | 3'UTR (SNP) | VAF 31/54 reads (57%) | called by muse, mutect2, varscan2
- NF1 | c.*3483C>T | 3'UTR (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- NUP58 | c.1435+2659T>C | Intron (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- PAK2 | c.*472T>A | 3'UTR (SNP) | VAF 187/289 reads (65%) | called by muse, mutect2, varscan2
- PBLD | c.691+91G>A | Intron (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- PDCL | c.*391T>A | 3'UTR (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- PDGFRA | c.2156+369G>C | Intron (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- PEAK1 | c.*414A>T | 3'UTR (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- PEBP1 | c.*104A>G | 3'UTR (SNP) | VAF 100/262 reads (38%) | catalogued as rs776665400; called by muse, mutect2, varscan2
- POU2F1 | c.*11372G>T | 3'UTR (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- PPP2CB | c.857+109C>T | Intron (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- PRLR | c.*2581C>T | 3'UTR (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- PRR23A | c.*460T>A | 3'UTR (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- PTEN | c.-23T>C | 5'UTR (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- PTGFRN | c.2167+79G>C | Intron (SNP) | VAF 16/40 reads (40%) | catalogued as rs1387287006; called by muse, mutect2, varscan2
- PTPN18 | c.1241-69G>T | Intron (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2, varscan2
- PTPN18 | c.1241-68C>T | Intron (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2, varscan2
- RBM4B | c.-12-219_-12-198delinsG | Intron (DEL) | VAF 6/36 reads (17%) | called by pindel, varscan2*
- RNF144A | c.*122G>A | 3'UTR (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- RPS4XP20 | n.638C>T | RNA (SNP) | VAF 17/123 reads (14%) | called by muse, mutect2, varscan2
- RTN3 | c.200-4588C>T | Intron (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- SHOX2 | chr3:158106194 A>C | 5'Flank (SNP) | VAF 23/112 reads (21%) | called by muse, mutect2, varscan2
- SLITRK2 | c.-3796G>C | 5'UTR (SNP) | VAF 57/105 reads (54%) | called by muse, mutect2, varscan2
- SNX13 | c.441-5380T>C | Intron (SNP) | VAF 62/94 reads (66%) | called by muse, mutect2, varscan2
- SREK1IP1 | c.*3557C>T | 3'UTR (SNP) | VAF 31/40 reads (78%) | called by muse, mutect2, varscan2
- STOML3 | c.*352A>C | 3'UTR (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- TGFB2 | c.-228G>T | 5'UTR (SNP) | VAF 35/81 reads (43%) | called by muse, mutect2, varscan2
- TNRC18 | c.*681C>A | 3'UTR (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- VAC14 | c.-210G>T | 5'UTR (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- VDR | chr12:47882810 G>A | 5'Flank (SNP) | VAF 7/14 reads (50%) | catalogued as rs770438356; called by muse, mutect2, varscan2
